Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3O7, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3O7-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[Redacted]	Service:	[Redacted]	Accession #:	[Redacted]
MRN:	[Redacted]	Visit #:	[Redacted]	Collected:	[Redacted]
DOB:	[Redacted]	Location:	[Redacted]	Received:	[Redacted]
Gender:	[Redacted]	Facility:	[Redacted]	Reported:	[Redacted]
HCN:	[Redacted]				
Ordering MD:	[Redacted]				
Copy To:	[Redacted]				

Specimen(s) Received

1. Parathyroid: RIGHT UPPER PARATHYROID QS
2. Parathyroid: Left lower parathyroid/QS
3. Thyroid: Total thyroid tie upper pole right lobe

Review Initials	[Signature]	

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy
2. No pathological diagnosis: Parathyroid (left lower) biopsy
3. Multifocal papillary carcinoma, dominant 4.7 cm, right: Thyroid
No pathological diagnosis: Parathyroids, right and left
- total thyroidectomy specimen

ICD-0-3
carcinoma, papillary, thyroid, 8260/3
Site: thyroid, NOS C73.9
lw
2/5/12

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.8 cm
	5.1 cm
	3.5 cm
	Left lobe:
	3.8 cm
	2.4 cm
	1.6 cm
	Isthmus +/- pyramidal lobe:
	2.0 cm
	3.1 cm
	2.2 cm
Specimen Weight:	69.32 g
Tumor Focality:	Multifocal, bilateral
	Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe

[page 2 of 3]
Surgical Pathology Consultation Report

Tumor Size: Greatest dimension: 5.0cm
Additional dimension: 4.7 cm
Additional dimension: 3.4 cm

Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Totally encapsulated

Tumor Capsular Invasion: Not identified
Present, extent minimal

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Isthmus

Tumor Size: Greatest dimension: 0.35cm

Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: None

Tumor Capsular Invasion: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

TNM Descriptors: Not applicable

Primary Tumor (pT): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension
(eg, extension to sternothyroid muscle or perithyroid soft tissues)

Regional Lymph Nodes (pN): pNX: Regional lymph nodes cannot be assigned
Number of regional lymph nodes examined: 0
Number of regional lymph nodes involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Other: multiple microcarcinomas, left

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "right upper parathyroid QS" consists of a tiny piece of tissue that measures 0.5 x 0.5 x 0.3 cm and weighs 0.017 g. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "left lower parathyroid qs" consists of a tiny piece of tissue that measures 0.2 x 0.2 x 0.1 cm. It is frozen for intraoperative consultation.

2A frozen section block resubmitted

3. The specimen labeled with the patient's name and as "total thyroid tie upper pole right lobe" consists of a thyroid gland that is oriented with a suture and weighs 69.32 g. The right lobe measures 4.8 cm SI x 5.1 cm ML x 3.5 cm AP, the left lobe measures 3.8 cm SI x 2.4 cm ML x 1.6 cm AP and the isthmus measures 2.0 cm SI x 3.1 cm ML x 2.2 cm AP. The

[page 3 of 3]
Surgical Pathology Consultation Report

external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with liquid bluing. The right lobe contains a well delineated, solid to cystic nodule that measures 4.7 cm SI x 5.0 cm ML x 3.4 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-O right lobe, superior to inferior

3P-W isthmus

3X-AG left lobe, superior to inferior

Quick Section Diagnosis

1. Right upper parathyroid: Parathyroid tissue identified.
Surgeon called 9.25 am.

2. Left lower parathyroid: Parathyroid tissue identified.
Surgeon called 9.45 am.

, MD

Source: NCI Genomic Data Commons file 06ddb4e1-1d64-474e-bbb8-d627cc4e570f (TCGA-EM-A3O7.F408FB89-12A6-4698-8E4B-C64F353C334D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).